Somatic mutation profile of tumor specimen TARGET-10-PAPFTJ-09A (aliquot TARGET-10-PAPFTJ-09A-01D) from TARGET case TARGET-10-PAPFTJ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,130 days).
Specimen TARGET-10-PAPFTJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e37506b9-6e69-48cf-918d-129a3fd312c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPFTJ-14A (Bone Marrow Normal), aliquot TARGET-10-PAPFTJ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d5b20a4-21b1-4d5f-bf76-ccbab634aaec

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, Nonsense Mutation 2, Splice Region 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSF2RB | c.322G>A p.V108I | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as COSV53257903; called by muse, mutect2, varscan2
- HTN1 | c.54C>T p.S18= | Splice Region (SNP) | VAF 5/12 reads (42%) | catalogued as rs182825270; called by muse, mutect2, varscan2
- ISL1 | c.354C>A p.D118E | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.134); catalogued as COSV57933482; called by muse, mutect2, varscan2
- KCNH5 | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs763607260, COSV100524909; called by muse, mutect2, varscan2
- LRRC74A | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 53/140 reads (38%) | catalogued as rs200930269, COSV53611406; called by muse, mutect2, varscan2
- RTN1 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.276); catalogued as rs1566709310; called by muse, mutect2, varscan2
- SEMA5B | c.2729G>A p.R910Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.03); catalogued as COSV99530744; called by muse, mutect2, varscan2
- STEAP2 | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 51/176 reads (29%) | catalogued as rs759069761, COSV55291911; called by muse, mutect2, varscan2
- FARP2 | c.1990T>C p.F664L | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRAMD1A | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NAALADL2 | c.866G>T p.R289M | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PKHD1L1 | c.11752C>A p.Q3918K | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PTCHD4 | c.80T>A p.L27H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RNF31 | c.2247_2251del p.D751Hfs*3 | Frame Shift Del (DEL) | VAF 73/228 reads (32%) | called by mutect2, pindel, varscan2
- SIX4 | c.703C>A p.R235S | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- IGHV1-45 | c.352del p.*118= | Silent (DEL) | VAF 18/85 reads (21%) | called by pindel*, varscan2
- RBM5 | c.2136C>T p.Y712= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs750310851; called by muse, mutect2, varscan2
- KSR2 | c.*21G>A | 3'UTR (SNP) | VAF 11/28 reads (39%) | catalogued as rs767356805, COSV100194694; called by muse, mutect2, varscan2
